Somatic mutation profile of tumor specimen C3N-01502-01 (aliquot CPT0065570009_1) from CPTAC case C3N-01502, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 75.4 years (27,522 days).
Specimen C3N-01502-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e9d4d5c-a9d5-47aa-ac9c-aed763f71053.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01502-31 (Blood Derived Normal), aliquot CPT0070700002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9122f6d1-1f94-405d-a23a-bb62601ab5a1

The open-access MAF lists 91 somatic variants for this specimen: 65 protein-altering or splice-affecting, 21 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 21, Nonsense Mutation 7, Intron 3, Splice Region 2, 5'UTR 2, Translation Start Site 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 48/775 reads (6%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2
- APOBEC1 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 9/217 reads (4%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.664); catalogued as rs1340514921; called by muse, mutect2
- ASH1L | c.6994G>T p.E2332* (on ENST00000368346 / NM_001366177.2; = p.E2327* on NM_018489.3) | Nonsense Mutation (SNP) | VAF 18/432 reads (4%) | catalogued as COSV64214920; called by muse, mutect2
- BAAT | c.427C>T p.R143* | Nonsense Mutation (SNP) | VAF 34/634 reads (5%) | catalogued as COSV52287479; called by muse, mutect2
- CD14 | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 14/380 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs1477907737; called by muse, mutect2
- COLGALT1 | c.951G>A p.V317= | Splice Region (SNP) | VAF 29/379 reads (8%) | catalogued as COSV53111399; called by muse, mutect2
- EXOC1 | c.723G>T p.M241I | Missense Mutation (SNP) | VAF 16/444 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as COSV100637853; called by muse, mutect2
- F2RL3 | c.604C>G p.L202V | Missense Mutation (SNP) | VAF 56/1192 reads (5%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.824); catalogued as rs774704645; called by muse, mutect2
- FAM124A | c.380C>A p.P127H (on ENST00000322475 / NM_001242312.2; = p.P163H on NM_145019.4) | Missense Mutation (SNP) | VAF 60/658 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99696426; called by muse, mutect2
- FMNL3 | c.279T>G p.S93R | Missense Mutation (SNP) | VAF 7/189 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1357973048; called by muse, mutect2
- GABRA5 | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 23/426 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.924); catalogued as rs1356654135; called by muse, mutect2
- HIVEP3 | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 36/408 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as rs762816658; called by muse, mutect2
- HLA-DRA | c.644C>A p.T215K | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.045); catalogued as COSV66622579; called by muse, mutect2
- IGLV3-1 | c.179A>T p.Q60L | Missense Mutation (SNP) | VAF 56/1110 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as rs375625744; called by muse, mutect2
- ITGB6 | c.1922C>T p.A641V | Missense Mutation (SNP) | VAF 14/356 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0.023); catalogued as COSV99324846; called by muse, mutect2
- ITSN2 | c.2328G>T p.M776I | Missense Mutation (SNP) | VAF 9/234 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61945775; called by muse, mutect2
- KRT83 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 67/1346 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.836); catalogued as rs751797447, COSV53339250; called by muse, mutect2
- LRPPRC | c.3005A>T p.E1002V | Missense Mutation (SNP) | VAF 32/565 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV99581352; called by muse, mutect2
- MEGF9 | c.720G>C p.E240D | Missense Mutation (SNP) | VAF 27/521 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as COSV100879404; called by muse, mutect2
- MKI67 | c.6117C>G p.I2039M | Missense Mutation (SNP) | VAF 37/662 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.344); catalogued as rs1323049349; called by muse, mutect2
- NFASC | c.359C>T p.A120V (on ENST00000339876 / NM_001378329.1; = p.A114V on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/463 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1177215477; called by muse, mutect2
- PCDHA11 | c.1531G>A p.A511T | Missense Mutation (SNP) | VAF 86/1900 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.192); catalogued as rs782716769; called by muse, mutect2
- PCDHGA8 | c.198C>G p.I66M | Missense Mutation (SNP) | VAF 20/268 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV53898242; called by muse, mutect2
- PYHIN1 | c.*7T>A | Splice Region (SNP) | VAF 19/209 reads (9%) | catalogued as rs866365420; called by muse, mutect2
- ROBO2 | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 18/253 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778332221, COSV59906905; called by muse, mutect2
- SHROOM4 | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 46/526 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1363295605; called by muse, mutect2
- TAP1 | c.278G>A p.W93* | Nonsense Mutation (SNP) | VAF 23/423 reads (5%) | catalogued as rs950606129, COSV100841138; called by muse, mutect2
- ABCA13 | c.1777A>G p.T593A | Missense Mutation (SNP) | VAF 14/329 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.013); called by muse, mutect2
- ABCA2 | c.2008C>T p.R670C (on ENST00000614293; = p.R640C on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/533 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ABCB6 | c.467T>C p.V156A | Missense Mutation (SNP) | VAF 24/595 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2
- ACADM | c.538G>A p.G180R | Missense Mutation (SNP) | VAF 36/533 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADGRA2 | c.3570C>G p.H1190Q | Missense Mutation (SNP) | VAF 30/676 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.205); called by muse, mutect2
- ADGRE1 | c.47A>T p.H16L | Missense Mutation (SNP) | VAF 13/295 reads (4%) | SIFT tolerated (0.55); PolyPhen benign (0.007); called by muse, mutect2
- ALS2 | c.3241G>C p.E1081Q | Missense Mutation (SNP) | VAF 38/890 reads (4%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.842); called by muse, mutect2
- BAZ2B | c.2446G>C p.E816Q | Missense Mutation (SNP) | VAF 14/330 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- BMPER | c.196C>G p.P66A | Missense Mutation (SNP) | VAF 44/868 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.039); called by muse, mutect2
- BRCC3 | c.107G>T p.G36V | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C16orf96 | c.2078T>A p.I693K | Missense Mutation (SNP) | VAF 14/443 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.206); called by muse, mutect2
- C2CD3 | c.5087C>G p.S1696* | Nonsense Mutation (SNP) | VAF 12/284 reads (4%) | called by muse, mutect2
- COMMD8 | c.64C>T p.Q22* | Nonsense Mutation (SNP) | VAF 15/374 reads (4%) | called by muse, mutect2
- COPRS | c.493C>G p.L165V | Missense Mutation (SNP) | VAF 18/472 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- DCLRE1C | c.855C>G p.I285M (on ENST00000378278 / NM_001350965.2; = p.I170M on NM_022487.4) | Missense Mutation (SNP) | VAF 22/571 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.713); called by muse, mutect2
- DDHD1 | c.173G>A p.G58E (on ENST00000323669; = p.G289E on NM_030637.3) | Missense Mutation (SNP) | VAF 11/250 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- FAM133A | c.398A>T p.K133I | Missense Mutation (SNP) | VAF 22/225 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.648); called by muse, mutect2
- FAM200B | c.728T>G p.V243G | Missense Mutation (SNP) | VAF 14/311 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2
- GLI3 | c.873A>T p.K291N | Missense Mutation (SNP) | VAF 56/1184 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GLYATL3 | c.742A>T p.N248Y | Missense Mutation (SNP) | VAF 25/464 reads (5%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.99); called by muse, mutect2
- MEPCE | c.1169G>T p.S390I | Missense Mutation (SNP) | VAF 15/337 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.276); called by muse, mutect2
- MID1IP1 | c.172G>A p.G58S | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- NABP1 | c.266A>C p.Y89S | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); called by muse, mutect2
- NEXMIF | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 13/153 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2
- NUTM1 | c.223G>T p.D75Y | Missense Mutation (SNP) | VAF 16/348 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2
- OTOG | c.7829G>T p.C2610F | Missense Mutation (SNP) | VAF 21/367 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PRORP | c.545T>A p.L182* | Nonsense Mutation (SNP) | VAF 18/366 reads (5%) | called by muse, mutect2
- RECQL4 | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 11/190 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- RIMBP2 | c.1280A>T p.E427V | Missense Mutation (SNP) | VAF 38/999 reads (4%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.69); called by muse, mutect2
- SACS | c.336G>C p.Q112H | Missense Mutation (SNP) | VAF 15/214 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- SLC15A1 | c.2029G>C p.E677Q | Missense Mutation (SNP) | VAF 15/494 reads (3%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.928); called by muse, mutect2
- SMG1 | c.8462T>C p.L2821S | Missense Mutation (SNP) | VAF 27/884 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- SMYD1 | c.1237C>T p.H413Y | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- SYT3 | c.1402+2T>G p.X468_splice | Splice Site (SNP) | VAF 26/626 reads (4%) | called by muse, mutect2
- TEPSIN | c.1376G>T p.G459V | Missense Mutation (SNP) | VAF 41/632 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2
- TESK2 | c.1057C>G p.H353D | Missense Mutation (SNP) | VAF 26/298 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2
- TNS4 | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 62/666 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.107); called by muse, mutect2
- TRIOBP | c.2816T>C p.L939P | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- C10orf71 | c.3975G>A p.P1325= | Silent (SNP) | VAF 18/434 reads (4%) | catalogued as rs936455982, COSV60506306; called by muse, mutect2
- DNAJA3 | c.15C>T p.C5= | Silent (SNP) | VAF 15/474 reads (3%) | catalogued as rs368800478; called by muse, mutect2
- DPF3 | c.774C>G p.P258= | Silent (SNP) | VAF 18/410 reads (4%) | called by muse, mutect2
- EXOC3L1 | c.1332G>T p.L444= | Silent (SNP) | VAF 26/534 reads (5%) | called by muse, mutect2
- GDF5 | c.438G>A p.L146= | Silent (SNP) | VAF 22/566 reads (4%) | catalogued as rs1460773430; called by muse, mutect2
- INSYN2B | c.324A>G p.P108= | Silent (SNP) | VAF 14/216 reads (6%) | called by muse, mutect2
- LIPC | c.615C>A p.P205= | Silent (SNP) | VAF 24/596 reads (4%) | called by muse, mutect2
- NEURL1 | c.1281G>A p.S427= | Silent (SNP) | VAF 14/266 reads (5%) | catalogued as COSV63915727; called by muse, mutect2
- NRIP1 | c.2103T>C p.S701= | Silent (SNP) | VAF 20/466 reads (4%) | catalogued as rs1441849670; called by muse, mutect2
- PEG3 | c.3669G>A p.S1223= | Silent (SNP) | VAF 20/319 reads (6%) | catalogued as rs559202627, COSV99689028; called by muse, mutect2
- PEX5L | c.195A>T p.S65= | Silent (SNP) | VAF 19/359 reads (5%) | called by muse, mutect2
- POU2F1 | c.1677C>T p.T559= (on ENST00000541643 / NM_001365848.1; = p.T582= on NM_002697.4) | Silent (SNP) | VAF 65/653 reads (10%) | catalogued as rs745888834; called by muse, mutect2, varscan2
- PTGER3 | c.1161T>C p.H387= | Silent (SNP) | VAF 26/330 reads (8%) | catalogued as COSV100138372; called by muse, mutect2
- SELENOT | c.318T>C p.P106= | Silent (SNP) | VAF 22/355 reads (6%) | called by muse, mutect2
- SLC15A4 | c.615A>G p.G205= | Silent (SNP) | VAF 57/481 reads (12%) | called by muse, mutect2, varscan2
- TAS2R60 | c.409T>C p.L137= | Silent (SNP) | VAF 19/379 reads (5%) | called by muse, mutect2
- TBC1D13 | c.1101G>T p.L367= | Silent (SNP) | VAF 22/508 reads (4%) | called by muse, mutect2
- TENM4 | c.6663G>A p.G2221= | Silent (SNP) | VAF 32/510 reads (6%) | catalogued as COSV53609505; called by muse, mutect2
- UGT3A1 | c.1398G>T p.G466= | Silent (SNP) | VAF 28/784 reads (4%) | called by muse, mutect2
- ZNF37A | c.1335A>G p.G445= | Silent (SNP) | VAF 21/409 reads (5%) | catalogued as rs1436769794; called by muse, mutect2
- ZSCAN26 | c.198A>T p.R66= | Silent (SNP) | VAF 16/357 reads (4%) | called by muse, mutect2
- CACNA1B | c.5223-1560C>T | Intron (SNP) | VAF 40/635 reads (6%) | catalogued as rs770886030, COSV53117835; called by muse, mutect2
- COPS3 | c.762+363A>C | Intron (SNP) | VAF 19/292 reads (7%) | called by muse, mutect2
- SNRPE | c.-10A>T | 5'UTR (SNP) | VAF 46/417 reads (11%) | called by muse, mutect2, varscan2
- TBC1D9B | c.2863+34C>G | Intron (SNP) | VAF 7/128 reads (5%) | called by muse, mutect2
- VPS29 | c.-12C>G | 5'UTR (SNP) | VAF 29/617 reads (5%) | called by muse, mutect2
